Somatic mutation profile of tumor specimen C3N-02426-01 (aliquot CPT0147180010) from CPTAC case C3N-02426, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G3; Age at diagnosis: 69.9 years (25,528 days).
Specimen C3N-02426-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 91a57741-61cf-46b8-a950-78d5bac96a01.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02426-72 (Blood Derived Normal), aliquot CPT0147220004; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6fcc3362-8722-4cc3-b8e1-8d698e0233df

The open-access MAF lists 52 somatic variants for this specimen: 33 protein-altering or splice-affecting, 12 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 12, Intron 5, Nonsense Mutation 2, 3'UTR 2, In Frame Del 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2235_2249del p.E746_A750del | In Frame Del (DEL) | VAF 46/379 reads (12%) | hotspot (GDC flag); catalogued as rs121913421, COSV51765119; ClinVar: drug response; called by mutect2, pindel
- ADAP1 | c.608A>G p.N203S | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.675); catalogued as rs1362513013, COSV56213682; called by muse, mutect2
- ELOA3C | c.689C>T p.T230M | Missense Mutation (SNP) | VAF 60/1794 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); catalogued as rs1323100445, COSV55294898; called by muse, mutect2
- GRIA3 | c.1164G>A p.M388I | Missense Mutation (SNP) | VAF 23/193 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as COSV52060773; called by muse, mutect2
- KIF27 | c.3050C>T p.S1017L | Missense Mutation (SNP) | VAF 26/374 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.003); catalogued as COSV52831111; called by muse, mutect2
- KRTAP21-2 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 21/321 reads (7%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.987); catalogued as COSV61684598; called by muse, mutect2
- NUP98 | c.3977A>C p.Q1326P (on ENST00000359171 / NM_001365126.1; = p.Q1309P on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/348 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.036); catalogued as rs1206887048, COSV61430311; called by muse, mutect2
- PCDH19 | c.533T>A p.I178N | Missense Mutation (SNP) | VAF 36/631 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as COSV55272358; called by muse, mutect2
- RAD50 | c.113A>G p.N38S | Missense Mutation (SNP) | VAF 42/314 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs750480943, COSV99529150; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- REG3G | c.20T>A p.L7Q | Missense Mutation (SNP) | VAF 17/238 reads (7%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.819); catalogued as COSV55449035; called by muse, mutect2
- RNF180 | c.158C>T p.A53V | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as COSV56961180, COSV56961415; called by muse, varscan2
- SAMD14 | c.622C>T p.R208W | Missense Mutation (SNP) | VAF 42/425 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); catalogued as rs780108620, COSV50305385; called by muse, mutect2
- SMC3 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1564788385; called by muse, mutect2
- THSD1 | c.275A>G p.Y92C | Missense Mutation (SNP) | VAF 21/194 reads (11%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.931); catalogued as rs373901957; called by muse, mutect2, varscan2
- ALDH3B2 | c.133del p.V45Wfs*12 | Frame Shift Del (DEL) | VAF 26/230 reads (11%) | called by mutect2, varscan2
- BMP15 | c.1066T>G p.S356A | Missense Mutation (SNP) | VAF 18/178 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); called by muse, mutect2
- CELSR2 | c.8372C>T p.P2791L | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2
- CTSF | c.908A>G p.N303S | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- GLYATL2 | c.361A>T p.K121* | Nonsense Mutation (SNP) | VAF 14/146 reads (10%) | called by muse, mutect2
- IMPG2 | c.782C>T p.S261F | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.5); called by muse, mutect2
- JPT2 | c.509G>A p.R170Q | Missense Mutation (SNP) | VAF 17/295 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- LEMD3 | c.28C>G p.Q10E | Missense Mutation (SNP) | VAF 20/220 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.112); called by muse, mutect2
- MCF2 | c.20G>A p.R7H | Missense Mutation (SNP) | VAF 36/552 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- MUC4 | c.6967G>T p.V2323F | Missense Mutation (SNP) | VAF 64/636 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.413); called by muse, varscan2
- PI4KA | c.3954G>C p.E1318D | Missense Mutation (SNP) | VAF 28/451 reads (6%) | SIFT tolerated (0.35); PolyPhen benign (0.147); called by muse, mutect2
- PLEKHG2 | c.1330C>G p.L444V | Missense Mutation (SNP) | VAF 32/335 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POLDIP2 | c.1048C>G p.P350A | Missense Mutation (SNP) | VAF 15/255 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.057); called by muse, mutect2
- PTPRB | c.353T>C p.V118A | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.005); called by muse, mutect2
- RBM39 | c.934A>C p.N312H | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- STRIP1 | c.2051C>G p.S684* | Nonsense Mutation (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2, varscan2
- TDRD12 | c.901G>A p.D301N | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.27); PolyPhen benign (0.11); called by muse, mutect2, varscan2
- TEX15 | c.3369G>T p.M1123I (on ENST00000256246; = p.M1506I on NM_001350162.2) | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.003); called by muse, mutect2
- ZNF654 | c.3238C>G p.Q1080E | Missense Mutation (SNP) | VAF 34/192 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- DCLK2 | c.1092A>G p.V364= | Silent (SNP) | VAF 9/195 reads (5%) | called by muse, mutect2
- DNMT3B | c.1233G>A p.G411= | Silent (SNP) | VAF 36/390 reads (9%) | called by muse, mutect2
- KCNJ16 | c.39G>A p.A13= | Silent (SNP) | VAF 21/280 reads (8%) | catalogued as rs779118420, COSV99388587, COSV99388869; called by muse, mutect2
- NCDN | c.513C>T p.H171= | Silent (SNP) | VAF 38/410 reads (9%) | called by muse, mutect2
- NOS3 | c.2778A>G p.P926= | Silent (SNP) | VAF 17/230 reads (7%) | catalogued as rs1389600257; called by muse, mutect2
- PIK3CG | c.897C>T p.N299= | Silent (SNP) | VAF 26/236 reads (11%) | catalogued as rs1220639059, COSV63247243, COSV63247651; called by muse, mutect2, varscan2
- PPP1R35 | c.351G>A p.R117= | Silent (SNP) | VAF 44/450 reads (10%) | catalogued as rs773011028; called by muse, mutect2
- SESN1 | c.241T>C p.L81= (on ENST00000356644 / NM_001199933.1; = p.L140= on NM_014454.3) | Silent (SNP) | VAF 36/212 reads (17%) | called by muse, mutect2, varscan2
- SLC46A3 | c.489A>G p.K163= | Silent (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- STOX1 | c.1626C>T p.I542= | Silent (SNP) | VAF 8/198 reads (4%) | catalogued as COSV53816702; called by muse, mutect2
- SYNE2 | c.1555C>T p.L519= | Silent (SNP) | VAF 14/272 reads (5%) | called by muse, mutect2
- ZNF469 | c.7347C>T p.C2449= (on ENST00000437464; = p.C2477= on NM_001367624.2) | Silent (SNP) | VAF 49/630 reads (8%) | catalogued as rs1381002315; called by muse, mutect2
- CFAP74 | c.4654-209G>A | Intron (SNP) | VAF 13/189 reads (7%) | catalogued as rs1434463492; called by muse, mutect2
- CRBN | c.751-26T>A | Intron (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- DTNBP1 | c.*17T>A | 3'UTR (SNP) | VAF 25/345 reads (7%) | called by muse, mutect2
- ILF3 | c.*310T>G | 3'UTR (SNP) | VAF 12/171 reads (7%) | called by muse, mutect2
- N4BP2L2 | c.1698-33851G>A | Intron (SNP) | VAF 12/143 reads (8%) | called by muse, mutect2
- PHB2 | c.867-15G>A | Intron (SNP) | VAF 42/638 reads (7%) | catalogued as rs782426484; called by muse, mutect2
- PSG5 | c.431-2787A>T | Intron (SNP) | VAF 48/227 reads (21%) | called by muse, mutect2, varscan2
